HCMI case HCM-SANG-0285-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Colon. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/e980e3c5-a9fb-42ad-ad02-b8bedc54ce23

Demographics
Sex at birth: male; Days to birth: -26,115 days (71.5 years before the index date).

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; ICD-10 code: C18.2; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Ascending colon; Classification of tumor: primary; Tumor grade: G2; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Uicc clinical stage: Stage IIIB; Uicc pathologic m: M0; Uicc pathologic n: N1; Uicc pathologic stage: Stage IIIB; Uicc pathologic t: T3; Uicc staging system edition: 7th.
   Pathology details: Perineural invasion present: No.
   Recorded as not given: neoadjuvant treatment (type not reported).

Molecular and laboratory tests
- BRAF mutation, nos: Positive.
- KRAS mutation, nos: Negative.
- MLH1 (IHC): Positive.
- MSH2 (IHC): Positive.
- MSH6 (IHC): Positive.
- PMS2 (IHC): Positive.
- Test (Sequencing, NOS): Positive; Mismatch repair mutation: Yes.

Exposures
- Tobacco smoking status: Current Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (6 samples)
- Sample HCM-SANG-0285-C18-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HCM-SANG-0285-C18-10A-01D-A80T-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample HCM-SANG-0285-C18-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-SANG-0285-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
- Samples HCM-SANG-0285-C18-85A-01D-A80T-32, HCM-SANG-0285-C18-85A-01R-A80W-32 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
